Somatic mutation profile of tumor specimen MP2PRT-PAVDUF-TMP1-A (aliquot MP2PRT-PAVDUF-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVDUF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 8.9 years (3,244 days).
Specimen MP2PRT-PAVDUF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21d7cbe5-45cd-4cfd-a1eb-68b27fab8aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDUF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDUF-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c957a7f-f828-49e4-9ff4-39ab9eeb7c44

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 156/299 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.750C>A p.D250E | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755623921; called by muse, mutect2, varscan2
- FOXO1 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 162/800 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV104427937, COSV104427953, COSV65426462; called by muse, mutect2, varscan2
- GRIA4 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs940677312, COSV99235172; called by muse, mutect2, varscan2
- OR13C8 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1229674544, COSV58611177, COSV58612031; called by muse, mutect2, varscan2
- PAGE3 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100892018, COSV66587113; called by muse, mutect2, varscan2
- PTPN13 | c.3718C>T p.R1240W (on ENST00000411767 / NM_080683.3; = p.R1221W on NM_006264.3) | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs894216631, COSV57403353; called by muse, mutect2
- CYP2F1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DENND1C | c.2303C>A p.P768Q | Missense Mutation (SNP) | VAF 250/563 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENAH | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 121/233 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGLV4-69 | chr22:22031462 ACTGGCATTCACACAGTGAC>G | Missense Mutation (DEL) | VAF 76/210 reads (36%) | called by pindel, varscan2*
- IQCH | c.2629C>A p.P877T | Missense Mutation (SNP) | VAF 159/341 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PCDH15 | c.4763T>A p.V1588D | Missense Mutation (SNP) | VAF 217/445 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TARS2 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUSC1 | c.332_333insAAGGCC p.F111delinsLRP | In Frame Ins (INS) | VAF 324/719 reads (45%) | called by mutect2, pindel, varscan2
- EFCAB10 | c.237C>T p.G79= | Silent (SNP) | VAF 135/341 reads (40%) | called by muse, mutect2, varscan2
- SLC16A2 | c.852G>T p.L284= | Silent (SNP) | VAF 24/972 reads (2%) | called by muse, mutect2
- SMIM28 | c.51G>T p.R17= | Silent (SNP) | VAF 36/524 reads (7%) | called by muse, mutect2
- TMEM72 | c.684G>A p.L228= | Silent (SNP) | VAF 32/705 reads (5%) | called by muse, mutect2
